Surgical pathology report (de-identified scan), TCGA case TCGA-VR-AA7B, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Barretos Cancer Hospital, specimen TCGA-VR-AA7B-01A (Primary Tumor).

Collect date:
(MM/DD/YYYY)

ICD-O-3

Carcinoma, squamous cell NOS
8070/3
Site: Esophagus, middle third
C15.4
JW 3/19/14

PATHOLOGY REPORT:

PRIMARY SITE: Esophagus (Mid third)

1 - "Product of esophagectomy":

- . Moderately differentiated squamous cell carcinoma, infiltrative and ulcerated.
- . Neoplasia measuring 7.0 cm in the longest axis and infiltrating to the external surface of the adventitia and adjacent adipose tissue that focally covers the wall.
- . Presence of lymphatic and perineural infiltrations.
- . Presence of foci of necrosis.
- . Proximal and distal surgical margins free of neoplastic involvement.
- . Metastatic squamous cell carcinoma in 9 of 27 lymph nodes (9/27), with the following distribution:
- 0/1 right paracardic;
- 0/1 left paracardic;
- 0/8 lesser curvature;
- 0/1 suprapyloric;
- 0/6 left gastric artery;
- 5/5 celiac trunk;
- 0/1 inferior paraesophageal;
- 4/4 middle third paraesophageal
- . Presence of capsular infiltration, with transposition, without nodal conglomerates formation.

2 - "Infracarinal lymph nodes":

- . Absence of neoplastic involvement in 5 lymph nodes (0/5).

3 - "Esophageal margin":

- . Free of neoplastic compromise.

HI/FAA Discrepancy		✓

Source: NCI Genomic Data Commons file 7b219ff7-652f-4e84-ad29-015b1e7cb0f7 (TCGA-VR-AA7B.0152E7FC-07E8-4894-BEDF-AA34D3648319.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).